Somatic mutation profile of tumor specimen TCGA-N5-A4RS-01A (aliquot TCGA-N5-A4RS-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RS, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IB; Age at diagnosis: 65.4 years (23,893 days).
Specimen TCGA-N5-A4RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0752bcd9-b022-40f4-bd24-e484955dcd24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RS-10A (Blood Derived Normal), aliquot TCGA-N5-A4RS-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b77d072b-f37f-454a-b3e0-6a1de8236bb7

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Del 5, Frame Shift Ins 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 10/13 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1057519938, COSV55881772, COSV55902438, COSV55902706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-2A>C p.X126_splice | Splice Site (SNP) | VAF 24/27 reads (89%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; called by muse, mutect2, varscan2
- DLGAP4 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1340006509, COSV59416443; called by muse, mutect2, varscan2
- MUC5AC | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious (0); catalogued as rs770614106, COSV100650750; called by muse, mutect2, varscan2
- PHC1 | c.595C>G p.H199D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.608); catalogued as COSV70418146; called by muse, mutect2, varscan2
- PTP4A3 | c.415G>A p.G139R (on ENST00000329397; = p.G114R on NM_007079.3) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs971191750, COSV100267394; called by muse, mutect2, varscan2
- SERPINB2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs527405738, COSV99449478; called by muse, mutect2, varscan2
- SLC11A1 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs750961294, COSV51916950; called by muse, mutect2, varscan2
- TONSL | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.965); catalogued as rs376067225, COSV68049362; called by muse, mutect2, varscan2
- ANKRD6 | c.93C>G p.N31K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMF | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 52/131 reads (40%) | called by muse, mutect2, varscan2
- CASQ1 | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- EPHA5 | c.2295G>T p.L765F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN4 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JAG1 | c.101_104del p.Q34Pfs*11 | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- L1CAM | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPC2 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PIK3R1 | c.661dup p.Q221Pfs*8 | Frame Shift Ins (INS) | VAF 92/207 reads (44%) | called by mutect2, pindel, varscan2
- SETDB1 | c.2643_2644del p.S881Rfs*18 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- SPRTN | c.458del p.H153Lfs*58 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- TAF5 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRAPPC11 | c.1736T>G p.I579R | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- TTF1 | c.2690del p.L897Wfs*18 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- TTLL3 | c.2109G>T p.Q703H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF830 | c.578_579del p.S193Cfs*10 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- AKR1C3 | c.642T>C p.V214= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, varscan2
- AMOT | c.2928G>A p.P976= (on ENST00000371959 / NM_001113490.1; = p.P567= on NM_133265.3) | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs776896032; called by muse, mutect2, varscan2
- C1QB | c.138C>T p.G46= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- MRPS11 | c.570G>A p.K190= | Silent (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- POTED | c.378C>T p.S126= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV55048084; called by muse, mutect2, varscan2
- THBS2 | c.2487C>T p.D829= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as rs201464524; called by muse, mutect2, varscan2
